Somatic mutation profile of tumor specimen C3L-07552-01 (aliquot CPT0431250006) from CPTAC case C3L-07552, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.2 years (21,973 days).
Specimen C3L-07552-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea26ab1d-0f8c-489b-82f4-fb043015b12e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07552-31 (Blood Derived Normal), aliquot CPT0431410004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a30ab7b4-5974-427f-9b79-3c1c67b4723c

The open-access MAF lists 1,650 somatic variants for this specimen: 1,204 protein-altering or splice-affecting, 386 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 835, Silent 386, Frame Shift Del 216, Frame Shift Ins 59, Nonsense Mutation 59, Intron 35, In Frame Del 13, Splice Region 12, 5'Flank 8, Translation Start Site 6, 5'UTR 6, RNA 5.

Variants (750 of 1,650; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 45/205 reads (22%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 54/234 reads (23%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL6A2 | c.1751del p.P584Lfs*12 | Frame Shift Del (DEL) | VAF 61/320 reads (19%) | catalogued as rs886044398; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 89/513 reads (17%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 32/273 reads (12%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 44/226 reads (19%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 70/168 reads (42%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NAGLU | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 32/422 reads (8%) | catalogued as rs138387856; ClinVar: likely pathogenic; called by muse, mutect2
- PAFAH1B1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 56/303 reads (18%) | catalogued as rs587784258, CM003040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs121918570, CM081767, COSV55023875, COSV55024947; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TMPRSS6 | c.1786del p.A596Pfs*8 | Frame Shift Del (DEL) | VAF 76/477 reads (16%) | catalogued as rs767094129, CD082210; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 56/291 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3013G>A p.V1005I | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs533057319; called by muse, mutect2, varscan2
- ABTB2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.784); catalogued as rs772690689, COSV54386680; called by muse, mutect2, varscan2
- AC138647.1 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 44/574 reads (8%) | catalogued as rs1448519768; called by muse, mutect2
- ACADS | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs751283667; called by muse, mutect2, varscan2
- ACSL1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780057916; called by muse, varscan2
- ACTG1 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59509952; called by muse, mutect2, varscan2
- ACVR1B | c.85del p.V29Sfs*57 | Frame Shift Del (DEL) | VAF 43/193 reads (22%) | catalogued as rs1425551425; called by pindel, varscan2
- ADAMTS7 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs112032898, COSV66307494; called by muse, mutect2, varscan2
- ADAMTS9 | c.4048C>T p.R1350W | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758184611, COSV55780071; called by muse, mutect2, varscan2
- ADAMTSL4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as rs777463641; called by muse, mutect2, varscan2
- ADGRB3 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 66/349 reads (19%) | catalogued as COSV65424133; called by muse, mutect2, varscan2
- ADGRD1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 89/411 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1192312096, COSV55439252; called by muse, mutect2, varscan2
- ADGRG2 | c.1006G>A p.G336S (on ENST00000379869 / NM_001079858.3; = p.G333S on NM_005756.4) | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs150585318; called by muse, mutect2, varscan2
- AFAP1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 73/320 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs374517381; called by muse, mutect2, varscan2
- AGAP3 | c.1855C>T p.R619* (on ENST00000622464; = p.R655* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/242 reads (18%) | catalogued as rs1265218429; called by muse, mutect2, varscan2
- AGBL3 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs183782913, COSV51950030; called by muse, mutect2, varscan2
- AHNAK | c.13927G>A p.V4643I | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.96); catalogued as rs750676449, COSV99945178; called by muse, mutect2, varscan2
- AKAP17A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 98/527 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV100002507; called by muse, mutect2, varscan2
- AKAP6 | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768663464, COSV104384195; called by muse, mutect2, varscan2
- ALDH7A1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs753014428, COSV68629052; called by muse, mutect2, varscan2
- ALDOA | c.665C>T p.A222V (on ENST00000642816 / NM_001243177.4; = p.A168V on NM_184041.5) | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1217024684; called by muse, varscan2
- ALG10B | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1297685544; called by muse, mutect2, varscan2
- ALK | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs770625956, COSV66571912; called by muse, varscan2
- ALKAL1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 86/504 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as COSV100660216; called by muse, mutect2, varscan2
- AMMECR1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 85/459 reads (19%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.012); catalogued as rs1267613870; called by muse, varscan2
- AMOTL1 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 67/430 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1468269371; called by muse, mutect2, varscan2
- ANK3 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs769597223; called by muse, mutect2, varscan2
- ANKRD11 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 57/378 reads (15%) | catalogued as CM158521, COSV56356166; called by muse, mutect2, varscan2
- ANKRD40 | c.294A>T p.E98D | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs199734034; called by muse, mutect2, varscan2
- ANO4 | c.2007-1G>T p.X669_splice (on ENST00000392977 / NM_001286615.2; = p.X634_splice on NM_178826.4) | Splice Site (SNP) | VAF 48/180 reads (27%) | catalogued as COSV100152870; called by muse, mutect2, varscan2
- APBA1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 96/511 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs774645762; called by muse, mutect2, varscan2
- APC2 | c.4634G>A p.R1545Q | Missense Mutation (SNP) | VAF 66/547 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs1389269266, COSV99279854; called by muse, mutect2, varscan2
- AR | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM092734, COSV101017945, COSV65955214; called by muse, mutect2, varscan2
- ARHGEF1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 56/281 reads (20%) | catalogued as rs144202833; called by muse, mutect2, varscan2
- ARHGEF10 | c.536C>T p.T179M (on ENST00000398564; = p.T155M on NM_014629.4) | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); catalogued as rs747480171; called by muse, mutect2, varscan2
- ARHGEF10 | c.2906G>A p.R969H (on ENST00000398564; = p.R944H on NM_014629.4) | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs766200020, COSV100035270; called by muse, mutect2, varscan2
- ARID1A | c.3010A>G p.T1004A | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs1254141515, COSV61374326; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 74/358 reads (21%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARID5B | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54428283; called by muse, varscan2
- ARPC3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs200224002; called by muse, mutect2, varscan2
- ARSI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs149628658; called by muse, mutect2, varscan2
- ARVCF | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 106/495 reads (21%) | catalogued as COSV54269643; called by muse, mutect2, varscan2
- ASTN1 | c.2357del p.P786Lfs*6 | Frame Shift Del (DEL) | VAF 45/232 reads (19%) | catalogued as COSV99920095; called by mutect2, pindel, varscan2
- ATF7IP | c.3409G>A p.V1137M | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.625); catalogued as rs771279244, COSV53768293; called by muse, mutect2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP2B3 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344012929; called by muse, mutect2, varscan2
- ATP2C2 | c.162del p.K55Rfs*28 | Frame Shift Del (DEL) | VAF 45/287 reads (16%) | catalogued as COSV52293271; called by mutect2, pindel, varscan2
- ATRX | c.4778C>T p.A1593V | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64883533; called by muse, mutect2, varscan2
- ATXN1L | c.1377del p.I460Lfs*11 | Frame Shift Del (DEL) | VAF 62/375 reads (17%) | catalogued as COSV70234780; called by mutect2, pindel, varscan2
- AUTS2 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750532676; called by muse, mutect2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 92/440 reads (21%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- BCOR | c.3661C>T p.Q1221* (on ENST00000378444 / NM_001123385.2; = p.Q1187* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 74/389 reads (19%) | catalogued as COSV60705021; called by muse, mutect2, varscan2
- BCOR | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 89/491 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs780396086, COSV60701707; called by muse, varscan2
- BDNF | c.60del p.M21* | Frame Shift Del (DEL) | VAF 66/343 reads (19%) | catalogued as rs1564941110; called by mutect2, pindel, varscan2
- BHLHE22 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs777526390; called by muse, mutect2, varscan2
- BICC1 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV54064103; called by muse, mutect2, varscan2
- BNIP3 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs1362335435; called by muse, mutect2, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 36/243 reads (15%) | catalogued as rs782133829; called by mutect2, varscan2
- BORA | c.740A>G p.D247G (on ENST00000613797; = p.D172G on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs1454550015; called by muse, mutect2, varscan2
- BTBD11 | c.1723C>T p.R575W (on ENST00000280758 / NM_001018072.2; = p.R112W on NM_001017523.2) | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018888722; called by muse, mutect2, varscan2
- C1QL3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1323244087; called by muse, mutect2, varscan2
- C20orf85 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148848088; called by muse, mutect2, varscan2
- C3 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as rs377113526; called by mutect2, varscan2
- C6orf201 | c.302del p.N101Mfs*8 | Frame Shift Del (DEL) | VAF 31/180 reads (17%) | catalogued as rs1438775096; called by mutect2, pindel, varscan2
- CACNA1G | c.2683C>T p.R895W | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1431189685; called by muse, mutect2, varscan2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2, varscan2
- CAMSAP1 | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773562023; called by muse, mutect2, varscan2
- CANT1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs1409328579, COSV56607116; called by muse, mutect2, varscan2
- CARD11 | c.3356C>T p.T1119M | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV67799741; called by muse, mutect2, varscan2
- CARMIL2 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs925043435; called by muse, mutect2
- CATSPERG | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs868320208; called by muse, mutect2
- CBARP | c.208G>A p.V70I (on ENST00000382477; = p.V76I on NM_152769.3) | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs750963325, COSV53068871; called by muse, mutect2
- CBX1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99848117; called by muse, mutect2
- CCAR1 | c.1295del p.N432Ifs*18 | Frame Shift Del (DEL) | VAF 46/304 reads (15%) | catalogued as rs951233372, COSV56273266; called by mutect2, pindel, varscan2
- CCDC166 | c.961del p.R321Gfs*41 | Frame Shift Del (DEL) | VAF 100/637 reads (16%) | catalogued as COSV72638932; called by mutect2, pindel, varscan2
- CCDC171 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.481); catalogued as rs142125441; called by muse, mutect2, varscan2
- CCDC172 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 50/238 reads (21%) | catalogued as rs1265543010; called by muse, mutect2, varscan2
- CCDC197 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1379494504, COSV100113655; called by muse, mutect2, varscan2
- CCDC78 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs763959604; called by muse, mutect2, varscan2
- CCL26 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs782783166; called by muse, mutect2
- CCNF | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1428900926, COSV53539584; called by muse, mutect2, varscan2
- CD101 | c.1967dup p.R657Efs*38 | Frame Shift Ins (INS) | VAF 46/320 reads (14%) | catalogued as rs769906221; called by mutect2, pindel, varscan2
- CD1E | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs192732251; called by muse, mutect2, varscan2
- CD70 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 71/412 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375410436, COSV104368713; called by muse, mutect2, varscan2
- CDH8 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs369877864; called by muse, mutect2, varscan2
- CDK12 | c.2608A>G p.S870G | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as COSV71000486; called by muse, mutect2, varscan2
- CDS1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs113432734, COSV55689356; called by muse, mutect2, varscan2
- CEL | c.2218C>T p.P740S (on ENST00000673714; = p.P737S on NM_001807.6) | Missense Mutation (SNP) | VAF 64/391 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs1212497532, COSV60829855; called by muse, mutect2, varscan2
- CEMIP | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs201373194; called by muse, varscan2
- CENPH | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | catalogued as rs757244178, COSV99295434; called by muse, mutect2, varscan2
- CEP112 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs373914387; called by muse, mutect2, varscan2
- CEP128 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 31/196 reads (16%) | catalogued as rs1476633409, COSV99383632; called by muse, mutect2, varscan2
- CEP290 | c.2390del p.K797Sfs*2 | Frame Shift Del (DEL) | VAF 13/113 reads (12%) | catalogued as rs781670422; ClinVar: uncertain significance; called by pindel, varscan2
- CFAP44 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs113101974, COSV55611403; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 85/469 reads (18%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFH | c.3617G>A p.R1206H | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs959443903, CM1512057, COSV100810285; called by muse, mutect2, varscan2
- CHST7 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs749451933; called by muse, mutect2, varscan2
- CHST8 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 99/388 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs758239416, COSV52859472; called by muse, mutect2, varscan2
- CLCN1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs139158852; called by muse, mutect2, varscan2
- CLCN4 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.285); catalogued as COSV66465530, COSV66467402; called by muse, mutect2
- CNTNAP3 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1403034127; called by muse, mutect2, varscan2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- COBL | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs765121031; called by muse, mutect2, varscan2
- COL11A1 | c.5167G>A p.V1723M | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV62194374; called by muse, mutect2, varscan2
- COL11A2 | c.3940C>T p.P1314S (on ENST00000341947 / NM_080680.3; = p.P1207S on NM_080679.2) | Missense Mutation (SNP) | VAF 106/456 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs1480175398, COSV100554613; called by muse, mutect2, varscan2
- COL26A1 | c.752G>A p.R251H (on ENST00000313669 / NM_001278563.3; = p.R249H on NM_133457.4) | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.083); catalogued as rs372045140; called by muse, mutect2, varscan2
- COL6A2 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768417049, COSV56003146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.2481dup p.Q828Tfs*8 | Frame Shift Ins (INS) | VAF 50/257 reads (19%) | catalogued as rs1222064379; called by mutect2, varscan2
- COL6A6 | c.5221C>T p.R1741C | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs367687833, COSV62029887; called by muse, mutect2, varscan2
- COLEC10 | c.336del p.G113Afs*30 | Frame Shift Del (DEL) | VAF 44/255 reads (17%) | catalogued as rs1286976627; called by mutect2, pindel, varscan2
- COPA | c.3520C>T p.R1174W | Missense Mutation (SNP) | VAF 30/413 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs775562836, COSV54098154; called by muse, mutect2
- CP | c.1503T>C p.S501= | Splice Region (SNP) | VAF 33/182 reads (18%) | catalogued as COSV99224316; called by muse, mutect2, varscan2
- CRIM1 | c.1133G>T p.R378M | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1481459333; called by muse, mutect2, varscan2
- CROCC | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs534002632, COSV100978141; called by muse, mutect2, varscan2
- CRTC1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs761116009; called by muse, varscan2
- CSF3 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56640235; called by muse, mutect2, varscan2
- CSMD2 | c.2205G>T p.K735N | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.83); catalogued as COSV99596629; called by muse, mutect2, varscan2
- CSMD2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 36/234 reads (15%) | catalogued as rs897426989; called by muse, mutect2, varscan2
- CSNK1D | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV53923252, COSV53927606; called by muse, mutect2
- CTNND2 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | catalogued as COSV100479185; called by muse, varscan2
- CTU1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1260647947; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs772257590; called by mutect2, varscan2
- CYP17A1 | c.675dup p.N226Qfs*12 | Frame Shift Ins (INS) | VAF 39/202 reads (19%) | catalogued as rs1458440922; called by mutect2, pindel, varscan2
- DCAF12L2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 34/534 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV63580533; called by muse, mutect2
- DCAF4L1 | c.173del p.K58Rfs*31 | Frame Shift Del (DEL) | VAF 79/344 reads (23%) | catalogued as COSV60786427; called by mutect2, pindel, varscan2
- DCST1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs375462437; called by muse, mutect2, varscan2
- DCST1 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as rs1464950081, COSV55058806; called by muse, mutect2, varscan2
- DDX42 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1328664423; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DDX60L | c.2171G>A p.G724D | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs200396904; called by muse, mutect2, varscan2
- DGAT2 | c.806A>G p.H269R | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1407056575; called by muse, varscan2
- DHX9 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172023063, COSV62358577; called by muse, mutect2, varscan2
- DIP2A | c.4207G>A p.V1403I | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370497841; called by muse, mutect2, varscan2
- DISP1 | c.3444del p.K1148Nfs*26 | Frame Shift Del (DEL) | VAF 53/266 reads (20%) | catalogued as rs1478802964; called by mutect2, pindel, varscan2
- DLC1 | c.2167C>T p.R723C (on ENST00000276297 / NM_001348081.2; = p.R286C on NM_006094.5) | Missense Mutation (SNP) | VAF 70/432 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs745427262, COSV52328343; called by muse, varscan2
- DLGAP3 | c.2731_2733del p.K911del | In Frame Del (DEL) | VAF 25/219 reads (11%) | catalogued as rs771547387; called by pindel, varscan2
- DMD | c.5646C>A p.Y1882* | Nonsense Mutation (SNP) | VAF 55/312 reads (18%) | catalogued as CM098425, COSV63741220; called by muse, mutect2, varscan2
- DNAH11 | c.2923G>T p.E975* | Nonsense Mutation (SNP) | VAF 41/257 reads (16%) | catalogued as rs776980207, COSV60949416; called by muse, mutect2, varscan2
- DNAH14 | c.5765del p.N1922Tfs*5 (on ENST00000445597; = p.N2462Tfs*5 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 37/161 reads (23%) | catalogued as rs1421316018; called by mutect2, pindel, varscan2
- DNAH9 | c.8107C>T p.L2703F | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as COSV99303799; called by muse, mutect2, varscan2
- DNAJC30 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1554611882; called by muse, mutect2, varscan2
- DNMT1 | c.268T>G p.L90V | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs779818604; called by muse, mutect2, varscan2
- DOC2A | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV58751703; called by muse, mutect2, varscan2
- DOP1B | c.5003T>C p.I1668T | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs753234829; called by muse, mutect2, varscan2
- DPP8 | c.989G>A p.R330H (on ENST00000341861 / NM_001320875.2; = p.R314H on NM_017743.6) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs61736631; called by muse, mutect2, varscan2
- DPY19L3 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755005968; called by muse, varscan2
- DRD4 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV104385289; called by muse, mutect2, varscan2
- DRG2 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs767155155; called by muse, mutect2, varscan2
- DRGX | c.530del p.G177Afs*35 | Frame Shift Del (DEL) | VAF 44/258 reads (17%) | catalogued as COSV100938309; called by mutect2, varscan2
- DSC1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs1173352297, COSV57144048, COSV99938360; called by muse, mutect2, varscan2
- DSC1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs1308728499, COSV57145346; called by muse, mutect2, varscan2
- DSC2 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1217851416, COSV51864000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL3 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 134/520 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as rs1280413475, COSV53049946; called by muse, varscan2
- EBAG9 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1292906417; called by muse, mutect2, varscan2
- EDEM2 | c.1044del p.L349Sfs*42 | Frame Shift Del (DEL) | VAF 80/393 reads (20%) | catalogued as rs751505029; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs753591380, COSV100668268; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs752796877, COSV62569525; called by muse, varscan2
- EFCAB13 | c.255del p.V86Lfs*22 | Frame Shift Del (DEL) | VAF 49/200 reads (25%) | catalogued as rs752272964, COSV58945324; called by mutect2, varscan2
- EFL1 | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs765023138, COSV51602311, COSV51606037; called by muse, mutect2, varscan2
- EFR3B | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993618185, COSV67837806; called by muse, mutect2, varscan2
- EGR3 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs763210546, COSV100416308; called by muse, mutect2, varscan2
- EHBP1L1 | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1237113373; called by muse, mutect2, varscan2
- EHF | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 36/201 reads (18%) | catalogued as COSV57668023, COSV99140841; called by muse, mutect2, varscan2
- EHMT1 | c.3628G>A p.V1210M | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1015778887, COSV66044936; called by muse, mutect2
- EIF2AK1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs777867248; called by muse, mutect2, varscan2
- ELP4 | c.747del p.K249Nfs*6 (on ENST00000350638; = p.K248Nfs*6 on NM_019040.5) | Frame Shift Del (DEL) | VAF 15/109 reads (14%) | catalogued as COSV63351931; called by mutect2, pindel, varscan2
- EPB41L4A | c.1577del p.N526Tfs*46 | Frame Shift Del (DEL) | VAF 44/226 reads (19%) | catalogued as rs755555590; called by mutect2, pindel, varscan2
- EPHA5 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs772410607, COSV99895911; called by muse, mutect2
- EPHX2 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs1231951536; called by muse, mutect2, varscan2
- EPS8L2 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs377264227; called by muse, mutect2, varscan2
- ERF | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370521331; called by muse, mutect2, varscan2
- ERN2 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 45/308 reads (15%) | catalogued as rs755206735, COSV55622362; called by muse, mutect2, varscan2
- ESPN | c.3535C>T p.L1179F | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1427215886; called by muse, mutect2, varscan2
- ESRRB | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as rs748968069; called by muse, mutect2, varscan2
- ETV4 | c.399dup p.R134Qfs*49 | Frame Shift Ins (INS) | VAF 46/234 reads (20%) | catalogued as rs745944421; called by mutect2, varscan2
- EVPL | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV56913110; called by muse, mutect2, varscan2
- F2RL3 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 99/486 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs757553981; called by muse, mutect2, varscan2
- FAM135B | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1161174796, COSV52740077; called by muse, mutect2, varscan2
- FAM184B | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53958874, COSV99034700; called by muse, mutect2, varscan2
- FAM83H | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 128/714 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs782584452; called by muse, mutect2, varscan2
- FAT4 | c.7579G>A p.A2527T | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs201007539, COSV58687043; called by muse, mutect2, varscan2
- FBP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748612104, COSV64695871; called by muse, mutect2
- FBXW5 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs767608977, COSV56403235; called by muse, mutect2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FKBP1C | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759314002; called by muse, mutect2, varscan2
- FOLR2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs768977412; called by muse, mutect2, varscan2
- FOXK2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58880005; called by muse, mutect2, varscan2
- FPR3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774077280; called by muse, mutect2, varscan2
- FTSJ3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs372104659; called by muse, mutect2
- FXR2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs868617231, COSV104376215; called by muse, mutect2, varscan2
- GALR1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1328433052; called by muse, mutect2, varscan2
- GBX1 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 110/574 reads (19%) | catalogued as COSV52548926; called by muse, mutect2
- GCC2 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs199920630; called by muse, mutect2, varscan2
- GGH | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs564440258, COSV52650155; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 52/276 reads (19%) | catalogued as rs763147690; called by mutect2, varscan2
- GIPR | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs191937467; called by muse, mutect2, varscan2
- GIT1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs149623045; called by muse, mutect2, varscan2
- GOLM1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.399); catalogued as rs757675677; called by muse, mutect2, varscan2
- GOLT1B | c.90del p.F30Lfs*14 | Frame Shift Del (DEL) | VAF 25/195 reads (13%) | catalogued as rs762177817; called by mutect2, pindel, varscan2
- GPATCH8 | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs763823154, COSV59193145; called by muse, mutect2, varscan2
- GPC5 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100992955, COSV100993890; called by muse, mutect2, varscan2
- GPR135 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as rs758910990; called by muse, mutect2, varscan2
- GPR139 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs146922265; called by muse, mutect2, varscan2
- GPR150 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs936606029, COSV66168552; called by muse, mutect2, varscan2
- GPR75 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290691545, COSV61829190; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIPAP1 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV64552522; called by muse, mutect2, varscan2
- GRSF1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.978); catalogued as rs547380528; called by muse, mutect2, varscan2
- GSG1L | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1272229676; called by muse, mutect2, varscan2
- GSPT1 | c.818C>T p.S273L (on ENST00000420576 / NM_001130007.2; = p.S411L on NM_002094.4) | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1414058348; called by muse, mutect2
- GTF3C1 | c.5590G>A p.A1864T | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs201376754; called by muse, mutect2, varscan2
- HCFC1 | c.4263dup p.C1422Lfs*2 | Frame Shift Ins (INS) | VAF 62/426 reads (15%) | catalogued as rs782587798; called by mutect2, varscan2
- HDAC11 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs141598514; called by muse, mutect2, varscan2
- HDAC4 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376894517; called by muse, mutect2, varscan2
- HDGFL1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 84/514 reads (16%) | catalogued as rs1251266103; called by muse, varscan2
- HECTD4 | c.12730C>T p.R4244W | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs941681149; called by muse, mutect2
- HERC4 | c.2311G>A p.G771S (on ENST00000395198 / NM_022079.3; = p.G763S on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53270410; called by muse, mutect2, varscan2
- HGFAC | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99060401; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 45/325 reads (14%) | catalogued as rs1558087190; called by mutect2, pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 27/162 reads (17%) | catalogued as rs761272507; called by mutect2, varscan2
- HS3ST2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 96/400 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54462844, COSV99757710; called by muse, mutect2, varscan2
- HSF4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99263558; called by muse, mutect2, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 56/327 reads (17%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IGF2R | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV63633466; called by muse, mutect2, varscan2
- IKBKE | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1344445148, COSV100898321, COSV100898398; called by muse, varscan2
- ILK | c.930_931del p.L311Rfs*11 | Frame Shift Del (DEL) | VAF 44/277 reads (16%) | catalogued as rs773109749; called by pindel, varscan2
- INA | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375016033, COSV63976358, COSV63976378; called by muse, mutect2, varscan2
- INF2 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs200948588; ClinVar: likely benign; called by muse, mutect2, varscan2
- INTS1 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.059); catalogued as rs754610575, COSV67178712; called by muse, mutect2, varscan2
- IPO7 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV65686035; called by muse, varscan2
- ISL1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs765046643; called by muse, mutect2, varscan2
- ISLR2 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 100/442 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV62301734; called by muse, mutect2, varscan2
- ITGAD | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs200967127, COSV101210427; called by muse, mutect2, varscan2
- ITGB4 | c.3928C>T p.R1310W | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369683446; called by muse, mutect2, varscan2
- ITPRID1 | c.2824-1G>A p.X942_splice | Splice Site (SNP) | VAF 15/166 reads (9%) | catalogued as COSV100087908; called by muse, mutect2
- JARID2 | c.2947G>A p.V983I | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.203); catalogued as rs751270951, COSV59194731; called by muse, mutect2, varscan2
- JPH2 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 112/482 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1273646828, COSV65902940; called by muse, mutect2, varscan2
- JUND | c.252del p.D85Tfs*12 | Frame Shift Del (DEL) | VAF 103/570 reads (18%) | catalogued as rs1555702626, COSV53254483; called by mutect2, pindel, varscan2
- KCNA4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); catalogued as rs756447343, COSV60251351; called by muse, mutect2, varscan2
- KCNB2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs547685470, COSV73048891; called by muse, mutect2, varscan2
- KCND2 | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100472973, COSV58580880; called by muse, mutect2, varscan2
- KCNE2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs368865412, COSV51709534; ClinVar: uncertain significance; called by muse, varscan2
- KCNJ9 | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1460189811, COSV58757555; called by mutect2, varscan2
- KCNV2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1292608116, COSV66057136; called by muse, mutect2, varscan2
- KCP | c.1625G>A p.G542D (on ENST00000620378; = p.G599D on NM_001366122.1) | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99926087; called by muse, mutect2, varscan2
- KDM4B | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs778616444; called by muse, mutect2, varscan2
- KDM5C | c.3460del p.E1154Nfs*110 | Frame Shift Del (DEL) | VAF 49/334 reads (15%) | catalogued as COSV64764320; called by mutect2, pindel, varscan2
- KIAA1109 | c.8740C>T p.R2914* | Nonsense Mutation (SNP) | VAF 56/205 reads (27%) | catalogued as COSV52698099; called by muse, mutect2, varscan2
- KIF1A | c.4864G>A p.V1622M (on ENST00000320389 / NM_001379639.1; = p.V1614M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766569322, COSV57482719; called by muse, mutect2, varscan2
- KIF26B | c.3385G>A p.V1129I | Missense Mutation (SNP) | VAF 47/505 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1286767364; called by muse, mutect2
- KLHL28 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61888270; called by muse, mutect2, varscan2
- KMT2D | c.11515del p.Q3839Sfs*42 | Frame Shift Del (DEL) | VAF 39/372 reads (10%) | catalogued as rs1565778024, CM1413055, COSV56407863; called by mutect2, pindel, varscan2
- KNDC1 | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs777553389; called by muse, mutect2, varscan2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 76/330 reads (23%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRT75 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs138832844; called by muse, mutect2, varscan2
- KRTAP16-1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs905030116; called by muse, mutect2, varscan2
- KRTAP29-1 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 39/571 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1292667035; called by muse, mutect2
- LARP1 | c.3112C>T p.R1038* (on ENST00000518297 / NM_033551.3; = p.R961* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 47/278 reads (17%) | catalogued as COSV100303563; called by muse, mutect2, varscan2
- LARP4 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1236024936; called by muse, mutect2, varscan2
- LCE2C | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.565); catalogued as COSV64228716; called by muse, mutect2, varscan2
- LDHD | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as rs750508829, COSV55581403; called by muse, mutect2, varscan2
- LHX5 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV55663681; called by muse, mutect2, varscan2
- LIG3 | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1007072275, COSV99252480; called by muse, mutect2, varscan2
- LMNB2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs367966814, COSV57587799; called by muse, mutect2, varscan2
- LMNTD1 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 9/222 reads (4%) | catalogued as rs1394989368; called by muse, mutect2
- LRIT1 | c.45G>C p.W15C | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs761755166, COSV63893828, COSV63893935; called by muse, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 54/333 reads (16%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP5 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 95/391 reads (24%) | catalogued as rs1234898008, CM053973, COSV53716312; called by muse, mutect2, varscan2
- LRRC4 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs767577383; called by muse, mutect2, varscan2
- LRRC8E | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1408136534; called by muse, mutect2
- LRRCC1 | c.3037dup p.T1013Nfs*7 | Frame Shift Ins (INS) | VAF 24/176 reads (14%) | catalogued as rs1288173822; called by mutect2, varscan2
- LRRK2 | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774443529, COSV54163172; called by muse, mutect2, varscan2
- LSS | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1170080720; called by muse, mutect2
- LYPD2 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368060572; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 26/262 reads (10%) | catalogued as rs753028254; called by mutect2, pindel
- MADD | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs201320304; called by muse, mutect2, varscan2
- MAN1C1 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as rs928469309; called by muse, mutect2, varscan2
- MAN2C1 | c.1995dup p.T666Hfs*19 | Frame Shift Ins (INS) | VAF 78/446 reads (17%) | catalogued as rs1204476436; called by mutect2, pindel, varscan2
- MAP1S | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.029); catalogued as rs1394169837; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK7 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs755374629, COSV100218969; called by muse, mutect2
- MAST4 | c.1684C>T p.R562* (on ENST00000403625 / NM_001164664.2; = p.R373* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as rs1220527593, COSV55115087; called by muse, mutect2, varscan2
- MBD6 | c.2080dup p.Q694Pfs*23 | Frame Shift Ins (INS) | VAF 15/108 reads (14%) | catalogued as rs762648935; called by mutect2, varscan2
- MBD6 | c.2200dup p.Q734Pfs*4 | Frame Shift Ins (INS) | VAF 90/341 reads (26%) | catalogued as rs749738168; called by mutect2, varscan2
- MCCC1 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs777026304; called by muse, mutect2, varscan2
- MDGA1 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 100/522 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.157); catalogued as rs1464541313; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 39/174 reads (22%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MED12 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61344051; called by muse, mutect2, varscan2
- MED14 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.151); catalogued as rs759092950, COSV61355817; called by muse, mutect2, varscan2
- MEFV | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs753723641; called by muse, mutect2, varscan2
- MEGF8 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1313603221; called by muse, mutect2
- MEGF8 | c.3406G>A p.V1136M (on ENST00000251268 / NM_001271938.2; = p.V1069M on NM_001410.3) | Missense Mutation (SNP) | VAF 86/462 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs771657070, COSV99235044; called by muse, mutect2, varscan2
- MFN1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750255582, COSV54941626; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 31/158 reads (20%) | catalogued as rs746398787; called by mutect2, varscan2
- MMEL1 | c.84del p.L29Cfs*8 | Frame Shift Del (DEL) | VAF 82/455 reads (18%) | catalogued as rs1168749408; called by mutect2, pindel, varscan2
- MMP28 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); catalogued as rs373463098; called by muse, varscan2
- MOB3B | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 77/360 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.684); catalogued as rs376064786; called by muse, mutect2, varscan2
- MOGAT2 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs370837360; called by muse, mutect2, varscan2
- MRTFB | c.2650dup p.R884Pfs*3 (on ENST00000571589 / NM_001365412.2; = p.R834Pfs*3 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 45/293 reads (15%) | catalogued as rs768684761; called by mutect2, varscan2
- MST1R | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs770039457; called by muse, mutect2, varscan2
- MTF2 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64772020; called by muse, mutect2, varscan2
- MUC2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs534651955; called by muse, mutect2
- MYC | c.1125del p.F375Lfs*19 (on ENST00000377970; = p.F390Lfs*19 on NM_002467.6) | Frame Shift Del (DEL) | VAF 57/411 reads (14%) | catalogued as COSV52373150; called by mutect2, pindel, varscan2
- MYCBPAP | c.1782G>A p.P594= | Splice Region (SNP) | VAF 45/196 reads (23%) | catalogued as rs140876616; called by muse, mutect2, varscan2
- MYO10 | c.2923G>C p.A975P | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.6); catalogued as rs771685798, COSV57028616; called by muse, mutect2, varscan2
- MYO7A | c.3689G>A p.R1230H | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368705036, COSV68687834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.7078del p.R2360Vfs*23 | Frame Shift Del (DEL) | VAF 48/283 reads (17%) | catalogued as COSV61850034; called by mutect2, pindel, varscan2
- MYPOP | c.1139dup p.H381Tfs*69 | Frame Shift Ins (INS) | VAF 58/258 reads (22%) | catalogued as rs757587344; called by mutect2, varscan2
- NBEAL2 | c.4121G>A p.G1374D | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.051); catalogued as rs886058598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBEAL2 | c.7033C>T p.R2345W | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161626848, CM134912; called by muse, mutect2, varscan2
- NCOA1 | c.1654G>A p.V552I | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs144977620; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 41/334 reads (12%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NEUROG3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 68/347 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs941232417; called by muse, mutect2, varscan2
- NEXN | c.1592_1594del p.R531del | In Frame Del (DEL) | VAF 47/235 reads (20%) | catalogued as rs754350672; called by pindel, varscan2
- NF1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350329837, COSV100645963, COSV62225453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKX2-1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 35/594 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1332287438; called by muse, mutect2
- NKX2-6 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 22/700 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1039509893, COSV61492765; called by muse, mutect2
- NLRP12 | c.1345del p.A449Pfs*38 | Frame Shift Del (DEL) | VAF 78/400 reads (20%) | catalogued as COSV100144783; called by mutect2, varscan2
- NLRP14 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100204448; called by muse, mutect2, varscan2
- NOP14 | c.1373A>G p.N458S | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs771475388; called by muse, mutect2, varscan2
- NOTCH4 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 70/379 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs776195186, COSV66684960; called by muse, mutect2, varscan2
- NPC1L1 | c.3042G>A p.W1014* | Nonsense Mutation (SNP) | VAF 41/248 reads (17%) | catalogued as rs1324407398, CM068050; called by muse, mutect2, varscan2
- NPM3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV100761666, COSV63381971; called by muse, mutect2, varscan2
- NPR1 | c.1891C>A p.L631M | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100902012; called by muse, mutect2, varscan2
- NPR2 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 65/314 reads (21%) | catalogued as rs767258629, COSV61311981; called by muse, mutect2, varscan2
- NRP1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779745790, COSV55159126; called by muse, mutect2, varscan2
- NSG1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs1378713826, COSV101207955; called by muse, mutect2, varscan2
- NUDCD3 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs748688442, COSV58126131; called by muse, mutect2, varscan2
- NUF2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs757297441; called by muse, mutect2, varscan2
- NUTM2G | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV63617672; called by muse, mutect2, varscan2
- NWD1 | c.3499C>A p.L1167M | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs950173956, COSV60339575, COSV60349352; called by muse, mutect2, varscan2
- OBSCN | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs374305092; called by muse, mutect2, varscan2
- ODF2 | c.30del p.R11Gfs*10 | Frame Shift Del (DEL) | VAF 53/339 reads (16%) | catalogued as COSV100654794; called by mutect2, pindel, varscan2
- OGFOD1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145842608, COSV60200687; called by muse, mutect2, varscan2
- OLFML2B | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1033126448; called by muse, mutect2, varscan2
- OLIG2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1371921665; called by muse, varscan2
- OPRD1 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 69/339 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs751435140; called by muse, mutect2, varscan2
- OR14A16 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs193920961, COSV62927186, COSV62927581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2L13 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs373253789, COSV63553860, COSV63558248; called by muse, mutect2, varscan2
- OR51B4 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs751480134, COSV66517628; called by muse, mutect2, varscan2
- OR5H1 | c.307dup p.S103Ffs*19 | Frame Shift Ins (INS) | VAF 53/263 reads (20%) | catalogued as rs774814732; called by mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- OSBP | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as rs1268888381; called by muse, mutect2, varscan2
- OTOG | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1245219844; called by muse, mutect2
- OTOG | c.6887G>A p.R2296H | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs775261055; called by muse, mutect2, varscan2
- PABPC1L | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369260391; called by muse, mutect2, varscan2
- PADI6 | c.127dup p.Q43Pfs*25 | Frame Shift Ins (INS) | VAF 34/252 reads (13%) | catalogued as rs1217323973; called by mutect2, pindel, varscan2
- PATL1 | c.2139G>A p.Q713= | Splice Region (SNP) | VAF 36/174 reads (21%) | catalogued as rs185908629; called by muse, mutect2, varscan2
- PCDHA12 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as rs371336139; called by muse, mutect2, varscan2
- PCDHA13 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56515710; called by muse, mutect2, varscan2
- PCDHA2 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1554120148, COSV65366098; called by muse, mutect2, varscan2
- PCDHA3 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs782417260, COSV63541935; called by muse, mutect2
- PCDHB12 | c.2033del p.P678Rfs*62 | Frame Shift Del (DEL) | VAF 92/632 reads (15%) | catalogued as rs1554287085; called by pindel, varscan2
- PCDHGA4 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV53938487; called by muse, mutect2, varscan2
- PCED1A | c.1269dup p.P424Afs*57 | Frame Shift Ins (INS) | VAF 55/314 reads (18%) | catalogued as rs772305388; called by mutect2, varscan2
- PCID2 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as COSV55815561; called by muse, mutect2, varscan2
- PCIF1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs140397899; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 24/147 reads (16%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCYOX1L | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as rs750959517, COSV99199311; called by muse, mutect2, varscan2
- PEAR1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150236151, COSV52772369; called by muse, mutect2, varscan2
- PFKM | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757746489; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 83/415 reads (20%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PGLYRP3 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs374163212; called by muse, varscan2
- PHRF1 | c.3269G>A p.R1090Q (on ENST00000264555 / NM_001286581.2; = p.R1089Q on NM_020901.4) | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs368921476; called by muse, mutect2, varscan2
- PIEZO2 | c.6105C>A p.C2035* | Nonsense Mutation (SNP) | VAF 26/204 reads (13%) | catalogued as rs1233037811, COSV99554592; called by mutect2, varscan2
- PIK3R2 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs1387844256, COSV55850922; called by muse, mutect2, varscan2
- PIP4P2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372629352, COSV53437599; called by muse, mutect2, varscan2
- PKD1 | c.12746G>A p.R4249H (on ENST00000262304 / NM_001009944.3; = p.R4248H on NM_000296.4) | Missense Mutation (SNP) | VAF 104/483 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1292157185; called by muse, mutect2, varscan2
- PKD1 | c.10745del p.P3582Rfs*3 (on ENST00000262304 / NM_001009944.3; = p.P3581Rfs*3 on NM_000296.4) | Frame Shift Del (DEL) | VAF 70/481 reads (15%) | catalogued as CD076868; called by mutect2, pindel, varscan2
- PKHD1L1 | c.3827A>G p.Y1276C | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs1390619098; called by muse, mutect2, varscan2
- PKP3 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 89/448 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs762556650, COSV100520950; called by muse, mutect2, varscan2
- PLAAT4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs368947257; called by muse, mutect2, varscan2
- PLEC | c.13651C>T p.R4551C (on ENST00000322810 / NM_201380.4; = p.R4441C on NM_000445.5) | Missense Mutation (SNP) | VAF 44/710 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200447944, COSV100515190; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHA4 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 108/466 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs779348368; called by muse, mutect2, varscan2
- PLEKHG1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100651686; called by muse, mutect2, varscan2
- PLEKHG4B | c.1172C>T p.T391M (on ENST00000283426; = p.T747M on NM_052909.5) | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as rs761186429; called by muse, mutect2, varscan2
- PLG | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs144869703, COSV57518417; called by muse, varscan2
- PLXNA1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 106/502 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV52526412; called by muse, mutect2, varscan2
- PLXNA3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781885592, COSV63754415; called by muse, mutect2, varscan2
- PLXNC1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 19/599 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs1425666080; called by muse, mutect2
- POTEA | c.1687del p.M563* (on ENST00000519951 / NM_001005365.2; = p.M517* on NM_001002920.1) | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | catalogued as rs905717954; called by mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 36/202 reads (18%) | catalogued as rs772047281; called by mutect2, varscan2
- POU6F2 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs535259814, COSV68877006; called by muse, mutect2, varscan2
- PPFIA2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100333438, COSV61030798; called by muse, varscan2
- PPIG | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs766143869, COSV99644092; called by muse, mutect2, varscan2
- PPM1M | c.716G>A p.R239Q (on ENST00000296487; = p.R400Q on NM_144641.4) | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs148260427; called by muse, mutect2, varscan2
- PPM1N | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55595518; called by muse, mutect2, varscan2
- PRDM8 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100325297; called by muse, mutect2, varscan2
- PRELID1 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs770853591; called by muse, mutect2
- PRICKLE3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 93/470 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs782086935; called by muse, mutect2, varscan2
- PRMT6 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as rs1285035659; called by muse, mutect2, varscan2
- PROB1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.694); catalogued as rs1032204676; called by muse, mutect2, varscan2
- PROSER1 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 42/176 reads (24%) | catalogued as rs764421721; called by muse, mutect2, varscan2
- PRR23D1 | c.150dup p.P51Tfs*27 | Frame Shift Ins (INS) | VAF 24/172 reads (14%) | catalogued as rs769392464; called by mutect2, varscan2
- PRSS22 | c.902del p.G301Vfs*113 | Frame Shift Del (DEL) | VAF 78/405 reads (19%) | catalogued as rs1321112076; called by mutect2, pindel, varscan2
- PRSS55 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as rs1480986971; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 28/158 reads (18%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PTCHD3 | c.2057del p.N686Mfs*4 | Frame Shift Del (DEL) | VAF 63/318 reads (20%) | catalogued as rs750923568; called by mutect2, pindel, varscan2
- PTK2B | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs753724315, COSV57767702; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 49/227 reads (22%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPRC | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61406654; called by muse, mutect2
- PTPRJ | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs1260334726; called by muse, mutect2
- PTPRJ | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV69250705; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 36/208 reads (17%) | catalogued as rs1179811215; called by mutect2, pindel, varscan2
- PTPRS | c.4753A>G p.I1585V | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs915320010; called by muse, mutect2, varscan2
- PUM3 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as rs375052256; called by muse, mutect2, varscan2
- RAB11FIP4 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs569471357; called by muse, varscan2
- RAB11FIP5 | c.1946dup p.K653Qfs*112 | Frame Shift Ins (INS) | VAF 37/298 reads (12%) | catalogued as rs35922357; called by mutect2, pindel, varscan2
- RABL6 | c.1557del p.W520Gfs*79 | Frame Shift Del (DEL) | VAF 93/425 reads (22%) | catalogued as rs755631481, COSV100272944; called by mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 53/304 reads (17%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RANBP17 | c.1922del p.N641Tfs*35 | Frame Shift Del (DEL) | VAF 14/145 reads (10%) | catalogued as rs1339102467; called by mutect2, pindel, varscan2
- RAPGEF4 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 41/242 reads (17%) | catalogued as rs761325788, COSV51379099; called by muse, mutect2, varscan2
- RASAL1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | catalogued as rs763097544, COSV55660550, COSV99921804; called by muse, mutect2, varscan2
- RASD1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs954460150, COSV51958180; called by muse, mutect2, varscan2
- RASIP1 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs367666886; called by muse, mutect2, varscan2
- RASIP1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1415174707; called by muse, mutect2
- RASSF5 | c.114del p.D39Tfs*127 | Frame Shift Del (DEL) | VAF 82/479 reads (17%) | catalogued as rs1344667401; called by mutect2, pindel, varscan2
- RASSF9 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 28/324 reads (9%) | catalogued as rs1309588415, COSV63434163, COSV63435081; called by muse, mutect2
- RBBP6 | c.2035C>T p.R679C | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs757145338, COSV60503738; called by muse, mutect2, varscan2
- RGL1 | c.1034del p.K345Rfs*12 (on ENST00000360851 / NM_001297672.2; = p.K380Rfs*12 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/243 reads (14%) | catalogued as rs1290470008; called by mutect2, pindel, varscan2
- RGS11 | c.265C>T p.R89C (on ENST00000397770 / NM_183337.3; = p.R68C on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs867939479, COSV99395810; called by muse, mutect2, varscan2
- RHOH | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372713940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMBP2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.943); catalogued as rs1182428381, COSV99900960; called by muse, mutect2, varscan2
- RIN3 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1321379069; called by muse, mutect2, varscan2
- RNF183 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs757935882, COSV99938108; called by muse, mutect2, varscan2
- RNF208 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 104/462 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769984433, COSV61289501; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 68/406 reads (17%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RP1 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779243716, COSV55116959; called by muse, mutect2, varscan2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 72/495 reads (15%) | catalogued as rs781249059; called by mutect2, pindel, varscan2
- RP1L1 | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs368855563; called by muse, mutect2, varscan2
- RPUSD3 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs774713989; called by muse, mutect2
- RTTN | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs748817683; called by muse, mutect2, varscan2
- RYR1 | c.7871G>A p.R2624H | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1214491630; called by muse, mutect2, varscan2
- RYR2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs758904216, COSV63665056; ClinVar: uncertain significance / not provided; called by muse, mutect2
- RYR2 | c.6431G>A p.R2144H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1243083109, COSV63666184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 140/675 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101610015; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 15/144 reads (10%) | catalogued as rs763290832; called by mutect2, varscan2
- SAT1 | c.306C>A p.G102= | Splice Region (SNP) | VAF 39/223 reads (17%) | catalogued as COSV63380680; called by muse, mutect2, varscan2
- SCARF2 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 55/558 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1327353509; called by muse, mutect2
- SCN7A | c.3436A>G p.T1146A | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV69272513; called by muse, mutect2, varscan2
- SEC31A | c.1652C>A p.S551Y (on ENST00000355196 / NM_001318120.1; = p.S512Y on NM_016211.4) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV52345780; called by muse, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 51/333 reads (15%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEMA4F | c.750_752del p.F251del | In Frame Del (DEL) | VAF 64/332 reads (19%) | catalogued as rs755597684; called by pindel, varscan2
- SEMA4G | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs553537753, COSV52966376; called by muse, mutect2
- SEMA5B | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs149599978; called by muse, mutect2, varscan2
- SERPINA5 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 75/401 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1224082103, COSV61574152; called by muse, mutect2, varscan2
- SETD5 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | catalogued as COSV56708543; called by muse, mutect2, varscan2
- SF3A2 | c.869del p.P290Rfs*156 | Frame Shift Del (DEL) | VAF 44/208 reads (21%) | catalogued as rs1404234638; called by mutect2, varscan2
- SFRP2 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 84/451 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs1405447492; called by muse, mutect2, varscan2
- SGK1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV52810268, COSV99397580; called by muse, mutect2
- SH3BP5L | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.182); catalogued as COSV100821997; called by muse, mutect2, varscan2
- SIM2 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1228880327, COSV51771799; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 52/271 reads (19%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC13A2 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as rs142009311; called by muse, mutect2, varscan2
- SLC16A12 | c.1405del p.T469Pfs*30 | Frame Shift Del (DEL) | VAF 49/244 reads (20%) | catalogued as COSV100369977; called by mutect2, pindel, varscan2
- SLC16A14 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 53/311 reads (17%) | catalogued as COSV54621965; called by muse, mutect2, varscan2
- SLC22A7 | c.730G>A p.V244M (on ENST00000372585 / NM_153320.2; = p.V242M on NM_006672.3) | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs773976393, COSV65354120; called by muse, mutect2, varscan2
- SLC25A6 | c.811_813del p.F271del | In Frame Del (DEL) | VAF 57/378 reads (15%) | catalogued as rs1200978666; called by pindel, varscan2
- SLC2A9 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 81/483 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs756028086; called by muse, mutect2
- SLC34A3 | c.1733dup p.K579Efs*14 | Frame Shift Ins (INS) | VAF 65/441 reads (15%) | catalogued as rs1353078679; called by mutect2, pindel, varscan2
- SLC46A2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 92/482 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs1211698547; called by muse, mutect2, varscan2
- SLC50A1 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 76/348 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1371253094, COSV100310239; called by muse, mutect2, varscan2
- SLC66A3 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs766277007; called by muse, varscan2
- SLC6A7 | c.915del p.L306Sfs*54 | Frame Shift Del (DEL) | VAF 53/269 reads (20%) | catalogued as rs1562093419; called by mutect2, pindel, varscan2
- SLITRK4 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556427931, COSV62023565; called by muse, mutect2, varscan2
- SLITRK4 | c.401A>C p.E134A | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567179; called by muse, mutect2, varscan2
- SLMAP | c.1416A>C p.Q472H (on ENST00000428312 / NM_001377924.1; = p.Q534H on NM_007159.5) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99908853; called by muse, mutect2, varscan2
- SMAD9 | c.1244G>A p.R415Q (on ENST00000379826 / NM_001127217.3; = p.R378Q on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763272058, COSV63206611; called by muse, mutect2, varscan2
- SMTN | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200037739, COSV60778916; called by muse, mutect2, varscan2
- SNRNP35 | c.443del p.K148Rfs*6 | Frame Shift Del (DEL) | VAF 66/368 reads (18%) | catalogued as rs1566105559; called by mutect2, varscan2
- SNRPB2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.266); catalogued as rs1454234729; called by muse, varscan2
- SNTG1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs571644446, COSV52432931; called by muse, mutect2, varscan2
- SNX18 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57993558; called by muse, mutect2
- SNX20 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 48/246 reads (20%) | catalogued as rs199531677, COSV100319303; called by muse, varscan2
- SNX21 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as rs1415202791, COSV61132552; called by muse, mutect2, varscan2
- SNX32 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs140929894, COSV57448860; called by muse, mutect2, varscan2
- SOBP | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1227936319; called by muse, mutect2, varscan2
- SORCS1 | c.2168G>A p.C723Y | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53877171; called by muse, mutect2
- SP100 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1472834401, COSV50987020; called by muse, mutect2
- SPAG6 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs768646423; called by muse, mutect2, varscan2
- SPAG8 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs200021660; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 43/206 reads (21%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPIC | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs1307034260; called by muse, mutect2, varscan2
- SPOCD1 | c.3282del p.R1095Gfs*32 | Frame Shift Del (DEL) | VAF 69/390 reads (18%) | catalogued as rs1455579753; called by mutect2, pindel, varscan2
- SPTBN2 | c.4252G>A p.V1418I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs777965059; called by muse, mutect2, varscan2
- SPTBN5 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781105743, COSV100311433; called by muse, mutect2, varscan2
- SRC | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs142822674; called by muse, mutect2, varscan2
- SRRM1 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as rs201182764; called by muse, mutect2, varscan2
- ST14 | c.369G>A p.A123= | Splice Region (SNP) | VAF 23/126 reads (18%) | catalogued as rs951566005; called by muse, varscan2
- TAOK1 | c.1737dup p.E580Rfs*23 | Frame Shift Ins (INS) | VAF 25/214 reads (12%) | catalogued as rs748972205; called by mutect2, pindel, varscan2
- TAOK2 | c.2992G>T p.G998C | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.615); catalogued as rs1183321738; called by muse, mutect2, varscan2
- TAS2R7 | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 93/436 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.06); catalogued as rs747855895; called by muse, mutect2, varscan2
- TBC1D19 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768839812; called by muse, mutect2, varscan2
- TBR1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 44/525 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101271401; called by muse, mutect2
- TBX22 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1403650886, COSV64785094, COSV64788566; called by muse, mutect2, varscan2
- TCERG1L | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1385295678; called by muse, varscan2
- TCF12 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs542664656, COSV51019483; called by muse, mutect2, varscan2
- TEX13B | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.496); catalogued as rs374604911; called by muse, mutect2, varscan2
- TEX14 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1445230871; called by muse, mutect2, varscan2
- TGFBR2 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs775640617, COSV55448729; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 77/349 reads (22%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TLCD3B | c.28dup p.V10Gfs*59 | Frame Shift Ins (INS) | VAF 50/280 reads (18%) | catalogued as rs780301705; called by mutect2, varscan2
- TLR5 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.294); catalogued as rs775204022, COSV104415978, COSV60557869; called by muse, mutect2, varscan2
- TMEM132D | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV101398472; called by muse, mutect2, varscan2
- TMEM150B | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs1026946207; called by muse, mutect2, varscan2
- TMEM177 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs767683363; called by muse, mutect2, varscan2
- TMEM177 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs774184214; called by muse, mutect2, varscan2
- TMEM184A | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1416645414, COSV52472185; called by muse, mutect2, varscan2
- TMEM204 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1295007332; called by muse, mutect2, varscan2
- TMEM8B | c.819+7G>A | Splice Region (SNP) | VAF 74/363 reads (20%) | catalogued as rs777381951, COSV65078296; called by muse, mutect2, varscan2
- TNK1 | c.1418G>T p.R473I (on ENST00000576812 / NM_001251902.2; = p.R468I on NM_003985.5) | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.68); catalogued as rs375682639; called by muse, mutect2, varscan2
- TNNT3 | c.587C>T p.P196L (on ENST00000397301 / NM_001367846.1; = p.P185L on NM_006757.4) | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1179208074; called by muse, mutect2, varscan2
- TNXB | c.8909C>A p.P2970H (on ENST00000647633; = p.P2723H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/383 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100926588; called by muse, mutect2
- TPPP | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as rs1195057918; called by muse, mutect2, varscan2
- TPST1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs769014115, COSV59174573; called by muse, mutect2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 35/231 reads (15%) | catalogued as rs770561785; called by mutect2, varscan2
- TREH | c.1580del p.G527Efs*18 | Frame Shift Del (DEL) | VAF 56/361 reads (16%) | catalogued as rs1555144046; called by mutect2, pindel, varscan2
- TRIM38 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 36/435 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as rs753172554; called by muse, mutect2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | catalogued as rs763121810; called by mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 39/264 reads (15%) | catalogued as COSV66660771; called by mutect2, varscan2
- TSPAN10 | c.456dup p.P153Afs*31 (on ENST00000574882 / NM_001290212.1; = p.P115Afs*31 on NM_031945.4) | Frame Shift Ins (INS) | VAF 110/486 reads (23%) | catalogued as rs771262491; called by mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 65/402 reads (16%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTN | c.98801G>A p.R32934H (on ENST00000591111; = p.R25510H on NM_003319.4) | Missense Mutation (SNP) | VAF 57/264 reads (22%) | PolyPhen probably damaging (0.982); catalogued as rs753392761, COSV60381995; called by muse, mutect2, varscan2
- TTN | c.2852del p.N951Mfs*2 (on ENST00000591111; = p.N905Mfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 22/189 reads (12%) | catalogued as COSV59940566; called by mutect2, pindel, varscan2
- TTYH2 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.06); catalogued as rs369516993, COSV53909848; called by muse, mutect2, varscan2
- TWF1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770428704; called by muse, mutect2, varscan2
- TXNDC15 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 51/273 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs758098996; called by muse, mutect2, varscan2
- TXNDC8 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs772456327, COSV100995447, COSV65725358; called by muse, mutect2, varscan2
- UBR5 | c.7713del p.F2571Lfs*4 | Frame Shift Del (DEL) | VAF 44/256 reads (17%) | catalogued as rs1471902646; called by mutect2, pindel, varscan2
- UNC5B | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs758678759; called by muse, mutect2, varscan2
- UPK3B | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs147530755; called by muse, mutect2, varscan2
- UQCRC1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs753634982, COSV52551636; called by muse, mutect2, varscan2
- USP11 | c.2338C>T p.R780W (on ENST00000218348; = p.R737W on NM_001371072.1) | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1247196906, COSV54474791, COSV54474832; called by muse, mutect2, varscan2
- UTRN | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV62332621; called by muse, mutect2, varscan2
- VCAN | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99427513; called by muse, mutect2, varscan2
- VENTX | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747307615; called by muse, mutect2, varscan2
- VPS13A | c.6095G>A p.R2032Q | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446441869; called by muse, mutect2, varscan2
- VPS13D | c.13141C>T p.R4381* | Nonsense Mutation (SNP) | VAF 23/232 reads (10%) | catalogued as rs753795620, COSV99168003; called by muse, mutect2
- VPS35L | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574948701; called by muse, mutect2
- VWA5B1 | c.2944C>T p.R982C (on ENST00000375079; = p.R977C on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs986754429; called by muse, mutect2, varscan2
- VWDE | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs555003498, COSV51728101; called by muse, mutect2, varscan2
- WDHD1 | c.2091del p.P699Qfs*44 | Frame Shift Del (DEL) | VAF 20/228 reads (9%) | catalogued as rs1390213036; called by mutect2, pindel
- WDR27 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as rs371337921; called by muse, mutect2, varscan2
- WDR45B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753663465, COSV101124421, COSV66408248; called by muse, mutect2, varscan2
- WDR6 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 77/393 reads (20%) | catalogued as rs767340730, COSV58244031; called by muse, mutect2, varscan2
- WDR62 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776569246, COSV99544383; called by muse, mutect2, varscan2
- WDR90 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs377544293; called by muse, mutect2, varscan2
- WNK4 | c.3641G>A p.R1214Q | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs547118032; called by muse, mutect2, varscan2
- WWC3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 68/414 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs750131978, COSV101081982; called by muse, mutect2, varscan2
- YTHDC1 | c.1136C>T p.T379M (on ENST00000344157 / NM_001031732.4; = p.T361M on NM_133370.4) | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447173446, COSV60009842; called by muse, mutect2, varscan2
- ZBTB17 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs1368741903, COSV100999051; called by muse, mutect2, varscan2
- ZBTB4 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 103/439 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as rs542157841; called by muse, mutect2, varscan2
- ZCCHC14 | c.2752G>A p.A918T (on ENST00000268616; = p.A1055T on NM_015144.3) | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51885452, COSV51887095; called by muse, mutect2
- ZDHHC18 | c.64del p.A22Rfs*99 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as rs1219651651; called by mutect2, pindel, varscan2
- ZFAND4 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV60858226; called by muse, mutect2, varscan2
- ZFP90 | c.1780del p.T594Pfs*57 | Frame Shift Del (DEL) | VAF 54/284 reads (19%) | catalogued as rs747260313; called by mutect2, varscan2
- ZMAT1 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 27/419 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs769382902; called by muse, mutect2
- ZMYM3 | c.2264A>G p.Q755R | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV58739663; called by muse, mutect2, varscan2
- ZNF214 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1168025119; called by muse, mutect2, varscan2
- ZNF219 | c.2157dup p.Q720Afs*13 | Frame Shift Ins (INS) | VAF 70/330 reads (21%) | catalogued as rs771569784; called by mutect2, varscan2
- ZNF292 | c.7016del p.N2339Ifs*3 | Frame Shift Del (DEL) | VAF 34/208 reads (16%) | catalogued as rs1562194636; called by mutect2, varscan2
- ZNF326 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs181139290; called by muse, mutect2, varscan2
- ZNF383 | c.1277A>G p.E426G | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV61939469; called by muse, mutect2
- ZNF462 | c.6347G>A p.R2116Q | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1274061321; called by muse, mutect2, varscan2
- ZNF469 | c.8612G>A p.G2871D (on ENST00000437464; = p.G2899D on NM_001367624.2) | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs79815243; called by muse, mutect2, varscan2
- ZNF497 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs1346954660; called by muse, varscan2
- ZNF503 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1426901194; called by muse, varscan2
- ZNF506 | c.513del p.K171Nfs*6 | Frame Shift Del (DEL) | VAF 39/214 reads (18%) | catalogued as rs1232032560; called by mutect2, pindel, varscan2
- ZNF514 | c.1195del p.T399Pfs*21 | Frame Shift Del (DEL) | VAF 32/180 reads (18%) | catalogued as rs755697811; called by mutect2, varscan2
- ZNF517 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 57/406 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.727); catalogued as rs1192989374; called by muse, mutect2, varscan2
- ZNF521 | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.756); catalogued as rs779117190, COSV100833105; called by muse, mutect2, varscan2
- ZNF557 | c.150G>A p.W50* (on ENST00000414706 / NM_001044388.2; = p.W57* on NM_024341.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 77/359 reads (21%) | catalogued as COSV53273197; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV58672240; called by muse, mutect2, varscan2
- ZNF572 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as rs201968418, COSV60002199; called by muse, mutect2, varscan2
- ZNF675 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); catalogued as rs763258845; called by muse, mutect2, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 58/308 reads (19%) | catalogued as rs1264060719; called by mutect2, pindel, varscan2
- ZNF722P | c.1034G>T p.R345I | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.076); catalogued as rs775126677, COSV57427333, COSV57427631; called by muse, mutect2, varscan2
- ZNF730 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781386333, COSV74168162; called by muse, mutect2, varscan2
- ZNF774 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62979638, COSV62979897; called by muse, mutect2, varscan2
- ZNF81 | c.1571A>G p.K524R | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.735); catalogued as COSV58575295; called by muse, mutect2, varscan2
- ZNF816 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV54411024; called by muse, mutect2, varscan2
- ZNF831 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV64037887; called by muse, mutect2
- ZNF98 | c.342del p.K114Nfs*9 | Frame Shift Del (DEL) | VAF 24/244 reads (10%) | catalogued as COSV63335911; called by pindel, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 48/292 reads (16%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14573G>A p.S4858N | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCF1 | c.1807A>G p.K603E (on ENST00000326195 / NM_001025091.2; = p.K565E on NM_001090.3) | Missense Mutation (SNP) | VAF 113/549 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABTB1 | c.927G>T p.E309D (on ENST00000232744 / NM_172027.3; = p.E167D on NM_032548.3) | Missense Mutation (SNP) | VAF 15/444 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.265); called by muse, mutect2
- AC073111.3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACADS | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ACP4 | c.27C>G p.H9Q | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, varscan2
- ADAM29 | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ADAM29 | c.722T>G p.V241G | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADCK5 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADCK5 | c.721dup p.D241Gfs*13 | Frame Shift Ins (INS) | VAF 74/394 reads (19%) | called by mutect2, pindel, varscan2
- ADCK5 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 99/471 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ADCY8 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADGRE3 | c.891del p.S298Vfs*26 | Frame Shift Del (DEL) | VAF 24/184 reads (13%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.4960A>G p.I1654V | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRV1 | c.10275G>T p.Q3425H | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ADO | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AEBP1 | c.2282A>T p.N761I | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- AFAP1L1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 49/283 reads (17%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGO4 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCY | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.9427G>T p.G3143C | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP6 | c.4516A>G p.K1506E | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AKR1C2 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- AL645922.1 | c.2312T>C p.M771T | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALB | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- AMIGO1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AMY2B | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AMZ2 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ANK1 | c.2757del p.D920Tfs*7 | Frame Shift Del (DEL) | VAF 55/372 reads (15%) | called by mutect2, pindel, varscan2
- ANK2 | c.8983del p.M2995Wfs*36 | Frame Shift Del (DEL) | VAF 64/308 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD36C | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.494); called by muse, mutect2
- ANKRD50 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKS6 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANXA6 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AOC1 | c.850_852del p.S284del | In Frame Del (DEL) | VAF 67/428 reads (16%) | called by pindel, varscan2
- ARAF | c.547del p.Q183Rfs*109 | Frame Shift Del (DEL) | VAF 61/318 reads (19%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 46/284 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF12 | c.1590-4_1622+13delinsAAGGATGACTGCTCAGGCTGTAGAGGAAGATAAGAGGTAACATAACTG p.X530_splice | Splice Site (DEL) | VAF 19/212 reads (9%) | called by pindel, varscan2*
- ARHGEF26 | c.1394T>C p.F465S | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID2 | c.1169del p.L390* | Frame Shift Del (DEL) | VAF 55/229 reads (24%) | called by mutect2, pindel, varscan2
- ARL13B | c.1127del p.P376Hfs*51 (on ENST00000394222 / NM_001174150.2; = p.P269Hfs*51 on NM_144996.4) | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by pindel, varscan2
- ASPHD2 | c.1031del p.F344Sfs*112 | Frame Shift Del (DEL) | VAF 50/270 reads (19%) | called by pindel, varscan2
- ASTN2 | c.2482del p.V828Sfs*39 (on ENST00000313400 / NM_001365069.1; = p.V777Sfs*39 on NM_014010.5) | Frame Shift Del (DEL) | VAF 57/259 reads (22%) | called by mutect2, pindel, varscan2
- ATF5 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 76/328 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ATP10A | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 37/498 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ATP13A3 | c.3422A>G p.Q1141R | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP6V0A1 | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATRNL1 | c.2698A>G p.T900A | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATXN2L | c.701del p.G234Vfs*33 | Frame Shift Del (DEL) | VAF 53/305 reads (17%) | called by mutect2, pindel, varscan2
- B4GALT7 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.011); called by muse, varscan2
- BAHCC1 | c.4477A>T p.S1493C | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BCKDK | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 41/492 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2
- BCL9 | c.3970_3972del p.Q1324del | In Frame Del (DEL) | VAF 70/330 reads (21%) | called by pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 70/358 reads (20%) | called by mutect2, varscan2
- BEND4 | c.264del p.G91Afs*23 | Frame Shift Del (DEL) | VAF 63/369 reads (17%) | called by mutect2, varscan2
- BEST4 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BMP6 | c.875del p.L292Cfs*6 | Frame Shift Del (DEL) | VAF 40/236 reads (17%) | called by mutect2, pindel, varscan2
- BOC | c.1982del p.P661Hfs*11 | Frame Shift Del (DEL) | VAF 49/306 reads (16%) | called by mutect2, pindel, varscan2
- BOP1 | c.1462del p.D488Tfs*12 | Frame Shift Del (DEL) | VAF 121/770 reads (16%) | called by mutect2, pindel, varscan2
- BRCA1 | c.4442C>T p.A1481V | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BRDT | c.215del p.N72Tfs*5 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | called by mutect2, pindel, varscan2
- BTBD8 | c.4416dup p.D1473* (on ENST00000636805 / NM_001376131.1; = p.D960* on NM_015237.4) | Frame Shift Ins (INS) | VAF 55/300 reads (18%) | called by mutect2, pindel, varscan2
- BTN2A2 | c.881del p.K294Rfs*56 | Frame Shift Del (DEL) | VAF 48/230 reads (21%) | called by mutect2, varscan2
- C16orf96 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- C1orf87 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- C2CD3 | c.5561A>G p.H1854R | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, varscan2
- C5AR2 | c.759del p.L254Wfs*58 | Frame Shift Del (DEL) | VAF 75/417 reads (18%) | called by mutect2, pindel, varscan2
- C6orf132 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CACNA1E | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CACNA1F | c.4409A>G p.D1470G | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA2D3 | c.2212A>G p.N738D | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CADPS | c.3067G>A p.V1023M | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CAMKK2 | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARNS1 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CASP8 | c.360del p.F120Lfs*18 (on ENST00000432109 / NM_033355.3; = p.F152Lfs*18 on NM_001228.4) | Frame Shift Del (DEL) | VAF 30/308 reads (10%) | called by mutect2, pindel
- CCDC115 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CCDC146 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC30 | c.1163A>G p.E388G (on ENST00000340612; = p.E345G on NM_001080850.3) | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC73 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CD160 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CD248 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 71/559 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CD74 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CDC14B | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH4 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK18 | c.1054A>G p.I352V (on ENST00000506784 / NM_212503.3; = p.I322V on NM_002596.4) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CDK9 | c.37del p.C13Vfs*35 | Frame Shift Del (DEL) | VAF 31/278 reads (11%) | called by mutect2, pindel, varscan2
- CELSR1 | c.7382A>C p.E2461A | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CELSR1 | c.5437C>T p.L1813F | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CELSR2 | c.5426G>A p.S1809N | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP112 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP162 | c.3293dup p.R1099Efs*46 | Frame Shift Ins (INS) | VAF 57/308 reads (19%) | called by mutect2, pindel, varscan2
- CEP290 | c.926A>T p.K309I | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CEP68 | c.1458del p.A487Lfs*3 | Frame Shift Del (DEL) | VAF 48/474 reads (10%) | called by mutect2, pindel, varscan2
- CEP76 | c.1157G>T p.S386I | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, varscan2
- CES1 | c.1035dup p.Y346Lfs*6 | Frame Shift Ins (INS) | VAF 55/350 reads (16%) | called by mutect2, pindel, varscan2
- CES1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CFAP91 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CGNL1 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CHD1 | c.3869C>A p.P1290Q | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CHD9 | c.3945_3946dup p.M1316Rfs*8 | Frame Shift Ins (INS) | VAF 46/254 reads (18%) | called by mutect2, varscan2
- CIAPIN1 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CMYA5 | c.2315C>T p.T772I | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CNIH1 | c.394dup p.Y132Lfs*56 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | called by mutect2, varscan2
- CNKSR1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- COL11A1 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COL4A1 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A1 | c.706del p.V236Sfs*78 | Frame Shift Del (DEL) | VAF 63/291 reads (22%) | called by mutect2, pindel, varscan2
- COL4A2 | c.1311del p.L439Sfs*14 | Frame Shift Del (DEL) | VAF 84/389 reads (22%) | called by mutect2, pindel, varscan2
- COL4A4 | c.3176del p.P1059Lfs*82 | Frame Shift Del (DEL) | VAF 48/305 reads (16%) | called by mutect2, pindel, varscan2
- COL6A3 | c.3790G>C p.V1264L | Missense Mutation (SNP) | VAF 79/367 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- COL6A6 | c.4905del p.G1636Efs*55 | Frame Shift Del (DEL) | VAF 47/211 reads (22%) | called by mutect2, varscan2
- COMTD1 | c.348_353del p.A123_L124del | In Frame Del (DEL) | VAF 76/422 reads (18%) | called by mutect2, pindel, varscan2
- CPA3 | c.707del p.N236Ifs*59 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, pindel, varscan2
- CPD | c.690dup p.A231Rfs*38 | Frame Shift Ins (INS) | VAF 45/251 reads (18%) | called by mutect2, pindel, varscan2
- CPT1B | c.221_223del p.F74del | In Frame Del (DEL) | VAF 74/347 reads (21%) | called by mutect2, pindel, varscan2
- CREBBP | c.5679del p.T1894Hfs*21 | Frame Shift Del (DEL) | VAF 74/489 reads (15%) | called by mutect2, pindel, varscan2
- CRLF1 | c.743del p.G248Afs*6 | Frame Shift Del (DEL) | VAF 108/552 reads (20%) | called by mutect2, pindel, varscan2
- CRNKL1 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CRYBA2 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSNKA2IP | c.1906T>C p.S636P | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CSPG4 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 115/487 reads (24%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.457del p.S153Hfs*23 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by pindel, varscan2
- CTDSPL2 | c.1283del p.N428Mfs*6 | Frame Shift Del (DEL) | VAF 18/205 reads (9%) | called by mutect2, pindel
- CTSF | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 67/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTSZ | c.24G>A p.W8* | Nonsense Mutation (SNP) | VAF 79/414 reads (19%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.4277C>T p.T1426I | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.401dup p.N134Kfs*10 (on ENST00000292535 / NM_181552.4; = p.N145Kfs*10 on NM_001913.5) | Frame Shift Ins (INS) | VAF 43/202 reads (21%) | called by mutect2, pindel, varscan2
- CUX1 | c.4421A>G p.N1474S | Missense Mutation (SNP) | VAF 94/375 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYBA | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CYP26C1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 115/530 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP7B1 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- DAGLA | c.1505dup p.L503Pfs*4 | Frame Shift Ins (INS) | VAF 78/389 reads (20%) | called by mutect2, pindel, varscan2
- DAP3 | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- DBF4 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- DCAF12 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 98/464 reads (21%) | called by muse, mutect2, varscan2
- DCHS1 | c.4448T>C p.V1483A | Missense Mutation (SNP) | VAF 76/457 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 65/334 reads (19%) | called by mutect2, pindel, varscan2
- DDIT3 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX17 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIS3L | c.2330del p.C777Lfs*13 (on ENST00000319212 / NM_001143688.3; = p.C694Lfs*13 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 50/292 reads (17%) | called by mutect2, pindel, varscan2
- DKK1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DMPK | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMRTA2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- DNAH11 | c.13465A>G p.S4489G | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH12 | c.2300C>A p.A767D | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DNAH3 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2
- DNAH5 | c.8343G>A p.M2781I | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- DNAH9 | c.9344C>T p.T3115I | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
900 further variants in this file (454 protein-altering or splice-affecting, 386 silent, 60 other) are not listed here.
